TCGA case TCGA-73-4676 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/195a5afb-b79f-44d2-9d12-884487630c2b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Dead; Days to death: 281 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.8 years (16,746 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Treatment intent type: Neoadjuvant; Days to treatment start: -74 days; Days to treatment end: -40 days; Number of cycles: 3; Treatment dose: 225 mg/m2; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 45 days; Days to treatment end: 66 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment end: 125 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.

Follow-up (5 entries)
- Days to follow up: 122 days; Disease response: Tumor Free.
- Days to follow up: 281 days; Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Adjuvant Therapy.
- Karnofsky performance status: 70; ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 164.

Other clinical attributes
- DLCO (% of predicted): 86; FEV1/FVC before bronchodilator (%): 67; FEV1 before bronchodilator (% of reference): 78.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 48; Tobacco smoking onset year: 1977; Tobacco smoking quit year: 2009.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-73-4676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-73-4676-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 20.
  Slide TCGA-73-4676-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-73-4676-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-73-4676-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.5; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 2.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: neo-adjuvant.
- Follow-up form 1: New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient received neo-adjuvant chemo for tumor submitted to TCGA.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 281 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 281 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 281 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-73-4676-01A-01D-1752-01): tumor purity 0.77, ploidy 1.31, whole-genome doublings 0.
